CCG case CUPP-B491 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ccc807d8-7224-450b-81ce-ec5a108071ee

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1948; Vital status: Dead; Days to death: 11 days; Year of death: 2008; Cause of death: Cancer Related.

Diagnoses (1)
1. Neoplasm, malignant, uncertain whether primary or metastatic: ICD-O-3 morphology code: 8000/9; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 59.3 years (21,661 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC clinical M: M1; AJCC pathologic M: M1; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver / Lung, NOS / Pancreas, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.

Follow-up (1 entry)
- Days to follow up: 11 days; Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B491-NT1-A: Sample type: FFPE Scrolls; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B491-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample CUPP-B491-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B491-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 30; Percent normal cells: 30; Percent necrosis: 40; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
